Somatic mutation profile of tumor specimen TCGA-CR-7373-01A (aliquot TCGA-CR-7373-01A-11D-2012-08) from TCGA case TCGA-CR-7373, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.9 years (24,448 days).
Specimen TCGA-CR-7373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cccacf8-2ebf-40b8-8686-8d34a75a1c4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7373-10A (Blood Derived Normal), aliquot TCGA-CR-7373-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86c29abb-f311-4583-9fa0-158e59825434

The open-access MAF lists 124 somatic variants for this specimen: 84 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 37, Nonsense Mutation 7, Frame Shift Del 4, Intron 3, Nonstop Mutation 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 17/30 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM120851, COSV52678166, COSV52736883, COSV52827473; called by muse, varscan2
- AGBL1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766761428, COSV101408287; called by muse, mutect2, varscan2
- AK1 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99802507; called by muse, mutect2, varscan2
- ALK | c.3531G>C p.Q1177H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101202814, COSV66594940; called by muse, mutect2, varscan2
- ANKRD30A | c.3400G>A p.E1134K (on ENST00000611781; = p.E1078K on NM_052997.2) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.587); catalogued as COSV64618086; called by muse, mutect2, varscan2
- ARGFX | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV100544240; called by muse, mutect2, varscan2
- ARHGAP32 | c.6171G>C p.Q2057H (on ENST00000310343 / NM_001378025.1; = p.Q1708H on NM_014715.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV100089650; called by muse, mutect2, varscan2
- ARID3C | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99427104; called by muse, mutect2
- ATP1A2 | c.2893C>A p.L965I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV100768210; called by muse, mutect2, varscan2
- C5 | c.4166C>G p.S1389C | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99798986; called by muse, mutect2, varscan2
- C9orf135 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.045); catalogued as COSV101019943; called by muse, mutect2, varscan2
- CCDC83 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs553174518, COSV54700993, COSV54703567; called by muse, mutect2, varscan2
- CLDND1 | c.123A>C p.E41D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.749); catalogued as COSV100360829; called by muse, mutect2, varscan2
- COL5A2 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100880928; called by muse, mutect2, varscan2
- DGKB | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV51761564, COSV51781556; called by muse, mutect2, varscan2
- DGKE | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99401252; called by muse, mutect2, varscan2
- DSCAM | c.1761G>C p.Q587H | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101261715; called by muse, mutect2
- EHD4 | c.1605G>T p.K535N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1158569399, COSV99588443; called by muse, mutect2, varscan2
- FAM53B | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.086); catalogued as rs140442850, COSV61561104; called by muse, mutect2, varscan2
- FBXL16 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100179176; called by muse, mutect2, varscan2
- FLG | c.11192C>T p.T3731I | Missense Mutation (SNP) | VAF 147/477 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs1186086613, COSV100912374; called by muse, mutect2, varscan2
- GRM3 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746444702, COSV100862985; called by muse, mutect2, varscan2
- HLA-A | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV65136444, COSV65138215; called by muse, mutect2
- IPO13 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs752950730, COSV100961365; called by muse, mutect2, varscan2
- IVL | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100908306, COSV64215387; called by muse, mutect2, varscan2
- LRSAM1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100032032; called by muse, mutect2, varscan2
- LYZL2 | c.585A>T p.*195Yext*42 (on ENST00000375318; = p.*149Yext*42 on NM_183058.3) | Nonstop Mutation (SNP) | VAF 87/257 reads (34%) | catalogued as COSV100940654; called by muse, mutect2, varscan2
- MAP10 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101406574; called by muse, mutect2, varscan2
- MAP1B | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99703027; called by muse, mutect2, varscan2
- MECOM | c.745G>T p.G249* (on ENST00000468789 / NM_001105078.4; = p.G437* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99245736; called by muse, varscan2
- MED1 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100328220; called by muse, mutect2, varscan2
- MUC5B | c.13163C>T p.T4388M | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs757967424, COSV71594699; called by muse, mutect2, varscan2
- MYLK | c.3901C>T p.R1301C | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs368321325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYNN | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs773957029, COSV100582366; called by muse, mutect2, varscan2
- NCOA7 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99997798; called by muse, mutect2, varscan2
- OR10J5 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100604833, COSV100604860; called by muse, mutect2, varscan2
- OR52H1 | c.189C>G p.F63L (on ENST00000322653; = p.F69L on NM_001005289.1) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV100497389; called by muse, mutect2, varscan2
- ORAI1 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs782169524, COSV100345520; called by muse, mutect2, varscan2
- OTOF | c.2521G>A p.E841K (on ENST00000272371 / NM_194248.3; = p.E94K on NM_004802.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs772729658, CM1513835, COSV55498536; called by mutect2, varscan2
- PCDHA5 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as COSV100972172; called by muse, mutect2, varscan2
- PCDHGA4 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); catalogued as COSV99548838; called by muse, mutect2, varscan2
- PDE8A | c.2253G>A p.Q751= | Splice Region (SNP) | VAF 19/77 reads (25%) | catalogued as rs755490265, COSV100052485; called by muse, mutect2, varscan2
- PDIA2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs367835970; called by muse, mutect2, varscan2
- PEPD | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99728872; called by muse, mutect2
- PPP4R3B | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55402526; called by muse, mutect2, varscan2
- PRRT3 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV99926791; called by muse, mutect2
- PTPRC | c.1309C>G p.L437V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV100723299; called by muse, mutect2, varscan2
- QKI | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV51692549, COSV99276733; called by muse, mutect2, varscan2
- RAB13 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100885303; called by muse, mutect2, varscan2
- RALGAPA1 | c.4520G>A p.R1507H | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as rs368647084; called by muse, mutect2, varscan2
- RNF10 | c.153G>C p.K51N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV100379064; called by muse, mutect2, varscan2
- RUVBL2 | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99669318; called by muse, mutect2, varscan2
- RXRG | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761649501, COSV100717956, COSV63232494; called by muse, mutect2, varscan2
- SEC24A | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV100524725, COSV59746071; called by muse, mutect2, varscan2
- SLC1A2 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53521552, COSV99555183; called by muse, mutect2, varscan2
- SLC66A2 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100673887; called by muse, mutect2
- SLIT1 | c.3232G>A p.D1078N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); catalogued as rs915059294, COSV99822746; called by muse, mutect2, varscan2
- SMARCA4 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778175819, COSV60785488, COSV60786996; called by muse, mutect2, varscan2
- SMARCE1 | c.1210A>G p.I404V | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs751165188, COSV99228520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SP140 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59448155; called by muse, mutect2, varscan2
- SRD5A3 | c.471G>C p.M157I | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99948197; called by muse, mutect2, varscan2
- SYNE1 | c.8509G>A p.E2837K (on ENST00000367255 / NM_182961.4; = p.E2844K on NM_033071.3) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV99583128; called by muse, mutect2, varscan2
- TACC2 | c.3084G>C p.W1028C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV100554290; called by muse, mutect2, varscan2
- TAF2 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.336); catalogued as COSV65422654; called by muse, mutect2, varscan2
- TANGO6 | c.2733G>C p.E911D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as COSV99937110; called by muse, mutect2
- TICRR | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs755775389, COSV51539480; called by muse, mutect2, varscan2
- TLN1 | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100148340; called by muse, mutect2
- TRPC1 | c.1963C>T p.H655Y (on ENST00000476941 / NM_001251845.2; = p.H621Y on NM_003304.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99859438; called by muse, mutect2, varscan2
- TRPV1 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1430734885, COSV51517649; called by muse, mutect2, varscan2
- UBE2R2 | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99602538; called by muse, mutect2, varscan2
- USP6 | c.2057G>A p.R686K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.097); catalogued as COSV100005129; called by muse, mutect2, varscan2
- VCAN | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764098299, COSV54103833; called by muse, mutect2, varscan2
- VPS52 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV101408765; called by muse, mutect2, varscan2
- WASL | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56133809; called by muse, mutect2, varscan2
- WDCP | c.1098C>G p.I366M | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99722262; called by muse, varscan2
- ZNF184 | c.1035G>C p.Q345H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV53003800; called by muse, mutect2, varscan2
- ZNF668 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770364347, COSV100336619, COSV100336986; called by muse, mutect2, varscan2
- ZNF789 | c.750T>G p.C250W | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100508039; called by muse, mutect2, varscan2
- ZNRF4 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs754053929, COSV55774924; called by muse, mutect2, varscan2
- CTRB2 | c.650del p.L217Rfs*? | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- MECOM | c.939_973del p.H313Qfs*7 (on ENST00000468789 / NM_001105078.4; = p.H501Qfs*7 on NM_004991.4) | Frame Shift Del (DEL) | VAF 6/82 reads (7%) | called by mutect2, pindel
- SREBF1 | c.1759_1760dup p.Q588Sfs*111 | Frame Shift Ins (INS) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- ZNF831 | c.2016del p.T673Pfs*32 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2*, pindel
- ANAPC15 | c.64C>A p.R22= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV56191467, COSV99921493; called by muse, mutect2, varscan2
- ATP2A1 | c.1305G>A p.E435= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100837472; called by muse, mutect2, varscan2
- CCND2 | c.840C>T p.T280= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99714158, COSV99714527; called by muse, mutect2
- CFAP58 | c.6T>A p.A2= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100459155; called by muse, mutect2, varscan2
- DDX20 | c.2019C>T p.Y673= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100862503; called by muse, mutect2, varscan2
- DIPK1B | c.1026C>T p.Y342= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs754141349, COSV100765539; called by muse, mutect2, varscan2
- DNTTIP2 | c.1146C>T p.P382= | Silent (SNP) | VAF 145/328 reads (44%) | catalogued as COSV100785225; called by muse, mutect2, varscan2
- DUSP10 | c.51C>T p.P17= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs748390873, COSV60456821; called by muse, mutect2, varscan2
- FGFRL1 | c.480C>T p.I160= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1283076647, COSV99294911; ClinVar: likely benign; called by muse, mutect2, varscan2
- GGTLC1 | c.444C>T p.G148= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as COSV53846323, COSV99601000; called by muse, mutect2, varscan2
- GPR83 | c.369C>G p.L123= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54717722; called by muse, mutect2, varscan2
- GRIN2B | c.2343G>T p.L781= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV101663217; called by muse, mutect2, varscan2
- IGSF9B | c.2292C>G p.L764= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100318608; called by muse, mutect2, varscan2
- ITGB4 | c.4662G>A p.E1554= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99564985; called by muse, mutect2, varscan2
- LLGL1 | c.2526C>T p.S842= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs376243078; called by muse, mutect2, varscan2
- MAN1A1 | c.1899C>T p.S633= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs569954263, COSV63787691; called by muse, mutect2, varscan2
- MS4A2 | c.153G>A p.L51= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99627570; called by muse, mutect2, varscan2
- MYCBP2 | c.7257C>G p.V2419= (on ENST00000357337; = p.V2457= on NM_015057.5) | Silent (SNP) | VAF 74/276 reads (27%) | catalogued as rs1164460719, COSV100632320; called by muse, mutect2, varscan2
- MYLK4 | c.1068C>G p.L356= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV99193935; called by muse, mutect2, varscan2
- NCOA7 | c.624G>A p.S208= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs973213076, COSV99996852; called by muse, mutect2, varscan2
- NCR2 | c.830G>A p.*277= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs1239457684, COSV100897213; called by muse, mutect2, varscan2
- NOTCH3 | c.3420C>T p.L1140= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs775270847, COSV99659194; called by muse, mutect2, varscan2
- OR10A2 | c.465C>T p.F155= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as COSV56299553; called by muse, mutect2, varscan2
- OR4K2 | c.903G>C p.L301= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100064819, COSV53851107; called by muse, mutect2, varscan2
- PRRC2B | c.765C>T p.L255= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100622363; called by muse, mutect2
- RBL1 | c.621T>C p.D207= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV100727333; called by muse, mutect2, varscan2
- RNF167 | c.687C>T p.V229= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV99337647; called by muse, mutect2, varscan2
- ROBO3 | c.3993C>T p.F1331= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1198309941, COSV60624191; called by muse, mutect2, varscan2
- S100A2 | c.225G>A p.E75= | Silent (SNP) | VAF 56/213 reads (26%) | catalogued as rs1188268636, COSV100905964; called by muse, mutect2, varscan2
- SH3GL3 | c.879C>G p.L293= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100197785, COSV61054645; called by muse, mutect2, varscan2
- SSX1 | c.402C>T p.N134= | Silent (SNP) | VAF 82/143 reads (57%) | catalogued as rs782539150, COSV100976418; called by muse, mutect2, varscan2
- TCOF1 | c.1143C>A p.S381= (on ENST00000377797 / NM_001135243.1; = p.S304= on NM_000356.4) | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100078547; called by muse, mutect2, varscan2
- TMEM131 | c.4014G>A p.A1338= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs762695162, COSV51771269; called by muse, mutect2, varscan2
- WDCP | c.1030C>T p.L344= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99722265; called by muse, varscan2
- WDCP | c.618C>G p.V206= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99722266; called by muse, mutect2, varscan2
- ZC3H3 | c.1881C>A p.G627= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99368783; called by muse, mutect2, varscan2
- ZNF621 | c.117G>A p.V39= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as rs750637744, COSV100182839; called by muse, mutect2, varscan2
- PGAM5 | c.719+686C>G | Intron (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100453153; called by muse, mutect2, varscan2
- PRR12 | c.51+137G>T | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99882599; called by muse, mutect2, varscan2
- TTLL11 | c.1539+52A>T | Intron (SNP) | VAF 33/153 reads (22%) | catalogued as COSV100389492; called by muse, mutect2, varscan2
